Somatic mutation profile of tumor specimen TARGET-10-PARKLL-09A (aliquot TARGET-10-PARKLL-09A-01D) from TARGET case TARGET-10-PARKLL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.3 years (4,868 days).
Specimen TARGET-10-PARKLL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f2225a2-7d92-43be-84a6-3c902a62ccf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARKLL-14A (Bone Marrow Normal), aliquot TARGET-10-PARKLL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/313db382-d9bd-49a6-998a-86e873751c16

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, 3'UTR 2, Silent 2, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCGF2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs1567941252, CM153571; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.4531C>T p.P1511S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs1297291684; called by muse, mutect2, varscan2
- DNAH5 | c.1184C>A p.S395Y | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54257141; called by muse, mutect2, varscan2
- ITGA10 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587768046; called by muse, mutect2, varscan2
- NRXN1 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 57/107 reads (53%) | catalogued as COSV58479167; called by muse, mutect2, varscan2
- C2CD3 | c.1528G>T p.V510F | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- HCRTR2 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LDAH | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZC3HC1 | c.734_735insG p.H245Qfs*15 | Frame Shift Ins (INS) | VAF 48/72 reads (67%) | called by mutect2, pindel, varscan2
- MICAL2 | c.3909G>A p.P1303= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs199655140, COSV99811941; called by muse, mutect2, varscan2
- MROH2B | c.2565G>A p.K855= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- AIFM3 | c.1652+29G>A | Intron (SNP) | VAF 32/62 reads (52%) | catalogued as rs1416187729; called by mutect2, varscan2
- BCORL1 | c.4306-2822C>T | Intron (SNP) | VAF 17/145 reads (12%) | catalogued as COSV99498132; called by muse, mutect2, varscan2
- CYB561A3 | c.*787C>T | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- GUSBP10 | n.596G>A | RNA (SNP) | VAF 7/35 reads (20%) | catalogued as rs779211057; called by muse, mutect2, varscan2
- MTSS1 | c.461-10T>C | Intron (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- PRDM2 | c.*32G>A | 3'UTR (SNP) | VAF 36/59 reads (61%) | catalogued as rs1302305800; called by muse, mutect2, varscan2
- RPL23A | c.209+67T>A | Intron (SNP) | VAF 43/73 reads (59%) | called by muse, mutect2, varscan2
